Somatic mutation profile of tumor specimen TCGA-A4-7997-01A (aliquot TCGA-A4-7997-01A-11D-2201-08) from TCGA case TCGA-A4-7997, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.0 years (24,486 days).
Specimen TCGA-A4-7997-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bbc6763-6b46-4b16-be1c-95034a59a469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7997-10A (Blood Derived Normal), aliquot TCGA-A4-7997-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55befadd-1b20-49ac-a878-d1b78c3a06f5

The open-access MAF lists 75 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 19, Frame Shift Del 2, Intron 1, 5'UTR 1, In Frame Del 1, Splice Site 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3280C>T p.H1094Y | Missense Mutation (SNP) | VAF 131/249 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913244, CM993668, COSV59256829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO10 | c.608A>T p.Y203F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52734053; called by muse, mutect2, varscan2
- ARHGAP26 | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV50835142; called by muse, mutect2, varscan2
- ASH1L | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 150/452 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV64210839; called by muse, mutect2, varscan2
- ATM | c.3993+2T>C p.X1331_splice | Splice Site (SNP) | VAF 32/90 reads (36%) | catalogued as COSV53742845; called by muse, mutect2, varscan2
- AXIN1 | c.142A>C p.K48Q | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV51990047; called by muse, mutect2, varscan2
- CDAN1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs752966516, COSV62333164; called by muse, mutect2, varscan2
- CDH17 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 68/85 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV50333427; called by muse, mutect2, varscan2
- CENPT | c.965A>T p.E322V | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54651041; called by muse, mutect2, varscan2
- CMAS | c.1124T>A p.V375E | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57557094; called by muse, mutect2, varscan2
- COL6A6 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757281522, COSV62031325; called by muse, mutect2, varscan2
- CP | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141532762; called by muse, mutect2, varscan2
- CREBBP | c.3512C>T p.T1171I | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52133008; called by muse, mutect2, varscan2
- CREBRF | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.052); catalogued as COSV51634804, COSV99755848; called by muse, mutect2, varscan2
- CTTNBP2 | c.4064C>G p.S1355C | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV50428639; called by muse, mutect2, varscan2
- CYP24A1 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV53775689; called by muse, mutect2, varscan2
- EAF2 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 137/256 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1019774829, COSV56543176; called by muse, mutect2, varscan2
- ENDOD1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.321); catalogued as COSV53590338; called by muse, mutect2, varscan2
- EPB41L3 | c.3182A>C p.K1061T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548420, COSV59461155; called by muse, mutect2, varscan2
- EXOC8 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.43); catalogued as COSV50478827; called by muse, mutect2, varscan2
- GLYR1 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.955); catalogued as COSV52170389; called by muse, mutect2, varscan2
- GRIN3A | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV62456247, COSV62456678; called by muse, mutect2, varscan2
- HERC1 | c.3125G>A p.W1042* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV71249048; called by muse, mutect2, varscan2
- HTT | c.3577C>A p.Q1193K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as COSV61865666; called by muse, mutect2, varscan2
- IQCN | c.2807G>C p.G936A | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.487); catalogued as COSV62748333; called by muse, mutect2, varscan2
- JAKMIP2 | c.2109C>A p.D703E | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV54610002; called by muse, mutect2, varscan2
- KDM6B | c.4230G>C p.W1410C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54684191; called by muse, mutect2, varscan2
- KMT2C | c.3564G>T p.Q1188H | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51470480; called by muse, mutect2, varscan2
- KMT2D | c.16341T>G p.N5447K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56464381; called by muse, mutect2, varscan2
- KRT33A | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as rs750471960, COSV50370244; called by muse, mutect2, varscan2
- LRRC23 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV50392001; called by muse, mutect2, varscan2
- MASTL | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60911730; called by muse, mutect2, varscan2
- MEP1B | c.749del p.N250Ifs*10 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs768998265; called by mutect2, pindel, varscan2
- NARF | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1013591686, COSV59112797; called by muse, mutect2, varscan2
- NIPBL | c.1706A>T p.E569V | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as COSV56958775; called by muse, mutect2, varscan2
- OOSP2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV53929579; called by muse, mutect2, varscan2
- PALB2 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55167671; called by muse, mutect2, varscan2
- PIGR | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62904594; called by muse, mutect2, varscan2
- PIK3C2A | c.3747T>G p.C1249W | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56404926; called by muse, mutect2, varscan2
- RERE | c.1753C>A p.R585S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61946190; called by muse, mutect2, varscan2
- SCRN2 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as COSV51636713; called by muse, mutect2, varscan2
- SEPTIN11 | c.808T>G p.F270V | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53583468; called by muse, mutect2, varscan2
- SLC41A1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100900441, COSV65651003; called by muse, mutect2, varscan2
- SNX9 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as rs1267083721, COSV101093877, COSV67585228; called by muse, mutect2, varscan2
- SPDEF | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV65001307; called by muse, mutect2, varscan2
- SPX | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57021313; called by muse, mutect2, varscan2
- STK11 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as rs758887235, COSV58826247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUMF1 | c.497T>G p.V166G | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV55994638; called by muse, mutect2, varscan2
- TECRL | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV67088885; called by muse, mutect2, varscan2
- U2AF2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58275281; called by muse, mutect2, varscan2
- WDR3 | c.2786A>G p.K929R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs763008067, COSV60463367; called by muse, mutect2, varscan2
- ZNF433 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV61399878; called by muse, mutect2, varscan2
- ADGRF3 | c.2823del p.L942Wfs*3 (on ENST00000311519 / NM_001145168.1; = p.L743Wfs*3 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- TMF1 | c.1086_1088del p.S363del | In Frame Del (DEL) | VAF 23/88 reads (26%) | called by pindel, varscan2
- APP | c.1272T>G p.P424= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV61001372; called by muse, mutect2, varscan2
- ARHGAP11A | c.399C>T p.L133= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100853138; called by mutect2, varscan2
- ARHGEF3 | c.393C>G p.S131= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV56329747; called by muse, mutect2, varscan2
- BNC2 | c.3066T>C p.S1022= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV66170712; called by muse, mutect2, varscan2
- C2orf73 | c.693G>T p.L231= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58311464; called by muse, mutect2, varscan2
- FRG2C | c.687C>A p.A229= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, varscan2
- GNB5 | c.273G>A p.G91= (on ENST00000261837 / NM_016194.4; = p.G49= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV55900273; called by muse, mutect2, varscan2
- HAGH | c.333T>C p.N111= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV68400855; called by muse, mutect2, varscan2
- IRF2BP2 | c.990C>A p.A330= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1026714861, COSV64015371; called by muse, mutect2, varscan2
- IRF6 | c.36C>T p.P12= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV65419862; called by muse, mutect2, varscan2
- LEFTY2 | c.568C>T p.L190= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV64747397; called by muse, mutect2, varscan2
- MAST2 | c.282T>C p.D94= | Silent (SNP) | VAF 82/243 reads (34%) | catalogued as COSV63619973; called by muse, mutect2, varscan2
- PDZK1 | c.1101T>C p.D367= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV58259822; called by muse, mutect2, varscan2
- RIPOR3 | c.1140C>T p.L380= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs748404052, COSV50395376; called by muse, mutect2, varscan2
- SYNM | c.3768G>T p.V1256= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1555486043, COSV50442908; called by muse, mutect2, varscan2
- TBC1D20 | c.795C>A p.V265= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as COSV62613144; called by muse, mutect2, varscan2
- ULK1 | c.3030C>G p.A1010= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV58858511; called by muse, mutect2, varscan2
- UNC5B | c.2274C>T p.L758= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV58978896; called by muse, mutect2, varscan2
- VWF | c.2856C>T p.H952= | Silent (SNP) | VAF 69/115 reads (60%) | catalogued as COSV54627557, COSV99780159; called by muse, mutect2, varscan2
- CRYGA | c.-1C>T | 5'UTR (SNP) | VAF 60/183 reads (33%) | catalogued as COSV100378232; called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-12092G>T | Intron (SNP) | VAF 58/171 reads (34%) | catalogued as COSV100857255; called by muse, mutect2, varscan2
